Somatic mutation profile of tumor specimen TCGA-DX-A3UB-01A (aliquot TCGA-DX-A3UB-01A-11D-A307-09) from TCGA case TCGA-DX-A3UB, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 54.4 years (19,862 days).
Specimen TCGA-DX-A3UB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d32c7434-0102-42e9-90c0-2c615cb5f8be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A3UB-10A (Blood Derived Normal), aliquot TCGA-DX-A3UB-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a007bd3-90cd-40c4-a06f-867aa5c3cd82

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 9, Silent 4, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AZU1 | c.634C>T p.H212Y | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.439); catalogued as rs759704289, COSV99297507; called by muse, mutect2, varscan2
- MAP3K9 | c.3244C>T p.P1082S (on ENST00000554752 / NM_001284230.1; = p.P1096S on NM_033141.4) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1286093311, COSV101173740; called by muse, mutect2
- MIEF2 | c.995A>G p.Q332R | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.713); catalogued as COSV100544169; called by muse, mutect2
- MYH1 | c.3544C>A p.L1182M | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.859); catalogued as COSV56846350, COSV99877236; called by muse, mutect2, varscan2
- NEUROG2 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100511978; called by muse, mutect2, varscan2
- OR2T8 | c.496T>C p.Y166H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs762111525; called by muse, varscan2
- STARD13 | c.2812G>A p.D938N (on ENST00000336934 / NM_001243476.3; = p.D820N on NM_052851.3) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs368225953; called by muse, mutect2, varscan2
- VWA8 | c.3379A>G p.T1127A | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV101023111; called by muse, mutect2, varscan2
- ESRP1 | c.431del p.K144Rfs*18 | Frame Shift Del (DEL) | VAF 38/102 reads (37%) | called by mutect2, pindel, varscan2
- ISY1-RAB43 | c.269G>C p.R90P | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PIM1 | c.356_365del p.I119Sfs*152 | Frame Shift Del (DEL) | VAF 19/82 reads (23%) | called by mutect2, pindel, varscan2
- CENPE | c.6090C>T p.S2030= | Silent (SNP) | VAF 41/135 reads (30%) | catalogued as COSV99479531; called by muse, mutect2, varscan2
- PCDHGA4 | c.624C>T p.Y208= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV53943296, COSV99549615; called by muse, mutect2
- TMEM252 | c.114G>T p.G38= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV101051166, COSV66065746; called by muse, mutect2
- ZNF76 | c.261C>T p.A87= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs376706823; called by muse, varscan2
